Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A00Y, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A00Y-01A (Primary Tumor).

Sample ID #:

Diagnosis:

Resectate of the large intestine under inclusion of a still moderately differentiated adenocarcinoma of the colorectal type, located 2.5 cm from the aboral resection margin and measuring 1.8 cm in diameter, with circumferential infiltration of the perirectal fatty tissue (max. infiltration depth into the fatty tissue of 0.6 cm). In close proximity, a further moderately differentiated colorectal carcinoma that has formed at the base of a tubular adenoma with severe dysplasia, with infiltration of the tunica submucosa and three tubular adenomas, partially with slight, partially with severe dysplasia (synonym: low- and high-grade intra-epithelial neoplasias). Tumor-free regional lymph nodes. Tumor-free large intestinal resection margins. Tumor-free mesenteric resection margin.

Tumor stage: pT3 (2) pN0 (0/31) pMX; G2, L0, V0. locallyR0.

ICD - 0 - 3

Adenocarcinoma, NOS 8140/3

Site: Rectum C20.9 3/21/11 *lu*

Tumor Malignancy History		☒

Source: NCI Genomic Data Commons file 2020fa0c-029c-494d-8679-9de03d59b1a6 (TCGA-AG-A00Y.00E12018-A30C-4FC4-81C2-FED102E6E5F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).